Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-A4C7, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-A4C7-01A (Primary Tumor).

[page 1 of 6]
Patient Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED]
Gender: [REDACTED]
HCN: [REDACTED]
Ordering MD: [REDACTED]

Service: Otolaryngology
Visit #: [REDACTED]
Location:
Facility:

Copath #: [REDACTED]
Collected: [REDACTED]
Resulted: [REDACTED]

Surgical Pathology Consultation Report

* Addended *

SPECIMEN(S) RECEIVED

1. Soft-Tissue: Left Postauricular Lesion
2. Lymph node: Left Perifacial lymph node
3. Neck: Left neck contents
4. Oral Cavity: Left composite resection body mandible, floor of mouth
5. Oral Cavity: Left sublingual gland
6. Oral Cavity: Anterior floor of mouth margin
7. Oral Cavity: Posterior floor of mouth margin
8. Oral Cavity: Posterior buccal margin
9. Oral Cavity: Deep floor of mouth margin
10. Lymph node: Lt. neck level 1A lymph node
11. Surgical Waste

ICD-0-3

Carcinoma, squamous cell, NOS
8070/3

DIAGNOSIS

1. Left postauricular lesion.
Seborrhheic keratosis. Site: floor of mouth, NOS C04.9
2. Left perifacial lymph node.
One lymph node positive for carcinoma (1/1). w 9/26/12
a. The involved lymph node measures 0.8 cm.
b. Focal extracapsular extension present.
3. Left neck contents.
Twenty-three lymph nodes negative for carcinoma (0/23).
4. Oral cavity; left body of mandible and floor of mouth.
Squamous cell carcinoma, poorly differentiated.
a. Maximum tumor diameter 4.5 cm.
b. Maximum tumour thickness 3.0 cm.
c. Perineural invasion present.
d. No lymphovascular invasion.
d. Margins negative for carcinoma.
e. Sections of mandible pending decalcification. An addendum report

[page 2 of 6]
will follow.

Status: supplemental

Page: 1 of 6

Patient Name:	[REDACTED]	Copath #:	[REDACTED]
MRN:	[REDACTED]	Service: Otolaryngology	Collected: [REDACTED]
DOB:	[REDACTED]	Visit #:	[REDACTED]
Gender:	[REDACTED]	Location:	Resulted: [REDACTED]
HCN:	[REDACTED]	Facility:	
Ordering MD:	[REDACTED]		

5. Left sublingual gland.
Sublingual negative for carcinoma.

6. Anterior floor of mouth margin.
Squamous mucosa negative for carcinoma.

7. Posterior floor of mouth margin.
Squamous mucosa negative for carcinoma

8. Posterior buccal margin.
Squamous mucosa negative for carcinoma.

9. Deep floor of mouth margin.
Negative for carcinoma.

10. Left neck level IA lymph node.
One lymph node negative for carcinoma (0/1)

11. Surgical waste.
Skin and bone with no pathologic changes. (Gross examination only)

SYNOPTIC DATA

Specimen Type:	Resection: Floor of mouth, body of
mandible	
Tumor Site:	Oral Cavity
Histologic Type:	Squamous cell carcinoma, conventional
Tumor Size:	Greatest dimension: 4.5 cm
	Tumor thickness: 3.0 cm
Histologic Grade:	G3: Poorly differentiated
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent

[page 3 of 6]
Perineural Invasion:

Margins:

Present

Margins uninvolved by tumor

pN1: Metastasis in a single

ipsilateral lymph node, 3 cm or less in greatest dimension for all
aerodigestive sites except nasopharynx

Number of regional lymph nodes

examined: 24

Status: supplemental

Page: 2 of 6

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

HCN: [REDACTED]

Ordering MD: [REDACTED]

Service: Otolaryngology

Visit #: [REDACTED]

Location: [REDACTED]

Facility: [REDACTED]

Copath #: [REDACTED]

Collected: [REDACTED]

Resulted: [REDACTED]

involved: 1

Number of regional lymph nodes

tumor: Present

Extra-capsular extension of nodal

assessed

PMX: Distant metastasis cannot be

*Pathologic Staging is based on AJCC/UICC TNM, 6th Edition

ELECTRONICALLY VERIFIED BY:

GROSS DESCRIPTION

1. The specimen labeled with the patient's name and as "left postauricular lesion", consists of an unoriented ellipse of tan skin, received in 10% buffered formalin. The specimen measures 3.3 x 0.9 x 0.5 cm in thickness. There is a 1.5 x 0.9 x 0.2 cm, tan-gray, friable lesion located 0.7 cm from the closest end tip and is close to both lateral margins. The remainder of the skin is grossly unremarkable. The surgical margins are painted with India ink.

1A end tips

1B- 1C remainder specimen serially sectioned and submitted in toto

2. The specimen container is labeled with the patient's name and as "left

[page 4 of 6]
perifacial lymph node" consists of a tan brown colored lymph node measuring 1.1 x 0.9 x 0.7 cm.

2A specimen bisected and submitted in toto

3. The specimen is labeled with the patient's name and "left neck contents". It consists of an oriented standard neck dissection with overall dimensions of 14.7 x 8.2 x 1.0 cm. The specimen is oriented on a green surgical towel. The submandibular gland measures 5.3 x 3.5 x 1.5 cm and is unremarkable. Multiple lymph nodes ranging from 0.2 to 2.2 cm are identified in multiple levels. Representative sections are submitted.

3A submandibular gland from level IB
3B one level IIA node

Status: supplemental

of 6

Patient Name	[REDACTED]	Service: Otolaryngology	Copath #	[REDACTED]
MRN:	[REDACTED]	Visit #:	Collected:	[REDACTED]
DOB:	[REDACTED]	Location:	Resulted:	[REDACTED]
Gender:	[REDACTED]	Facility:		
HCN:	[REDACTED]			
Ordering MD:	[REDACTED]			

3C three level IIA nodes
3D one level IIB node bisected
3E- 3F multiple level III nodes in each block
3G three level III nodes
3H one level III node bisected
3I multiple level IV nodes
3J one level IV node
3K one level IV node bisected

4. The specimen is labeled with the patient's name and as "left composite resection (body of mandible, floor of mouth)". It consists of an anterior and posterior portion of the body of mandible with attached floor of mouth and soft tissue measuring 6.3 AP x 3.5 SI x 3.6 ML cm. It includes a portion of mandible with no teeth. There is a tumor arising in the floor of mouth. The tumor measures 4.5 AP x 3.0 SI x 2.7 ML cm. The tumor is tan-white in color and firm. There is some involvement of bone by the tumour. The tumor is located at 0.1 cm from the closest anterior mandibular margin. Remaining margins are as follows: 1.1 cm from the lateral buccal and soft tissue margin, 1.0 cm from the medial mucosa and soft tissue margin, 0.9 cm from the posterior mucosal and soft tissue margin, and 0.1 cm on the posterior mandibular margin. The resection margin is painted with Silver nitrate. Three pieces of tumor

[page 5 of 6]
and two pieces of normal tissue are stored frozen. Representative sections are submitted.

- 4A anterior mucosal and soft tissue margin with tumor
- 4B medial mucosal and soft tissue margin with tumor
- 4C posterior mucosal and soft tissue margin with tumor
- 4D lateral buccal and soft tissue margin with tumor
- 4E anterior mandibular margin, en face after decalcification
- 4F posterior mandibular margin, en face after decalcification
- 4G-4H mandible in relation to tumor after decalcification

5. The specimen container is labeled with the patient's name and as "left sublingual gland" and consists of a yellow-tan lymph node measuring 2.9 x 1.5 x 1.0 cm.

5A- 5B specimen bisected and submitted in toto

6. The specimen is labeled with the patient's name and as "anterior floor of mouth margin". It consists of a fragment of tissue measuring 1.5 x 0.4 x 0.3 cm. The specimen is submitted in toto for frozen section.

6A frozen section control

Status: supplemental

Page: 4 of 6

Patient Name: [REDACTED]	Service: Otolaryngology	Copath #: [REDACTED]
MRN: [REDACTED]	Visit #: [REDACTED]	Collected: [REDACTED]
DOB: [REDACTED]	Location: [REDACTED]	Resulted: [REDACTED]
Gender: [REDACTED]	Facility: [REDACTED]	
HCN: [REDACTED]		
Ordering MD: [REDACTED]		

7. The specimen is labeled with the patient's name and as "posterior floor of mouth margin". It consists of a fragment of tissue measuring 1.5 x 0.5 x 0.3 cm. The specimen is submitted in toto for frozen section.

7A frozen section control

8. The specimen is labeled with the patient's name and as "posterior buccal margin". It consists of a fragment of tissue measuring 1.0 x 0.3 x 0.3 cm. The specimen is submitted in toto for frozen section.

8A frozen section control

9. The specimen is labeled with the patient's name and as "deep floor of mouth margin". It consists of a fragment of tissue measuring 1.2 x 0.5 x 0.2 cm. The specimen is submitted in toto for frozen section.

9A frozen section control

[page 6 of 6]
10. The specimen container is labeled with the patient's name and as "left neck level IA lymph node" consists of a tan-yellow lymph node measuring 0.8 x 0.7 x 0.4 cm.
10A submitted in toto

11. The specimen container labeled with the patient's name and as "surgical waste", contains three pieces of tissue in 10% buffered formalin. The tissue consists of one piece of skin with underlying soft tissue measuring 2.0 x 1.7 x 0.5 cm and two pieces of bone with soft tissue attached measuring from 3.5 x 3.0 x 2.1 to 4.0 x 1.0 x 0.2 cm. No gross abnormalities are identified. No material is submitted for histologic examination.

QUICK SECTION

6. Inferior floor of mouth, margin: Negative for carcinoma
7. Posterior floor of mouth, margin: Negative for carcinoma
8. Posterior buccal, margin: Negative for carcinoma
9. Deep floor of mouth, margin: Negative for carcinoma
Reported to

Status: supplemental

Page: 5 of 6

Patient Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED]
Gender: [REDACTED]
HCN: [REDACTED]
Ordering MD: [REDACTED]

Service: Otolaryngology
Visit #: [REDACTED]
Location:
Facility:

Copath #: [REDACTED]
Collected: [REDACTED]
Resulted: [REDACTED]

Addendum Status: Signed Out
Date Reported:

Addendum Comment

Decalcified sections show invasion of cortical and medullary bone by squamous cell carcinoma. The bone margins are negative for tumor.

Source: NCI Genomic Data Commons file f6d4207b-a9c7-4e11-94e0-a2bc538ed629 (TCGA-CQ-A4C7.DD00F089-12E7-4029-A849-4003E3628D4A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).